Surgical pathology report (de-identified scan), TCGA case TCGA-JW-A5VK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site BLN - Baylor, specimen TCGA-JW-A5VK-01A (Primary Tumor).

[page 1 of 3]
Result History

Result Date and Time

Status

Priority

Final result

Routine

Report Assistance Message

ICD-O-3
Carcinoma, squamous cell
papillary 8652/3
Site: Cervix NOS
C53.9
QD 4/4/13

Component Results

Surgical Pathology:

(note)

Name

Date of Birth

Hospital Number

Location Peoples

SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

PATHOLOGIC DIAGNOSIS

A. CERVIX, "SECTION", BIOPSY:

- DETACHED FRAGMENTS OF HIGH GRADE SQUAMOUS INTRAEPITHELIAL LESION (HSIL), CANNOT RULE OUT INVASIVE SQUAMOUS CELL CARCINOMA

B. UTERINE CERVIX, 9 O'CLOCK, BIOPSY:

- DETACHED FRAGMENTS OF HIGH GRADE SQUAMOUS INTRAEPITHELIAL LESION (HSIL), CANNOT RULE OUT INVASIVE SQUAMOUS CELL CARCINOMA

C. UTERINE CERVIX, 12 O'CLOCK, BIOPSY:

- INVASIVE, POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, PAPILLARY TYPE
- SEE MICROSCOPIC DESCRIPTION

D. ENDOCERVICAL CURETTAGE:

- INVASIVE, POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, PAPILLARY TYPE
- SEE MICROSCOPIC DESCRIPTION

[page 2 of 3]
Staff Pathologist

Pertinent Clinical Information

...ar-old ... with HGSIL on Pap smear.

Severe cervical HGSIL/dysplasia.

Gross Description

Specimen Material: A- Cervical section; B- Cervical biopsy at 9 o'clock; C- Cervical biopsy at 12 o'clock; D- Endocervical curettage/

The case is received in four parts, each labeled with the patient's name, medical record number and given accession number, and it is accompanied by a requisition form labeled with the same name and accession number.

Part A: Received in formalin labeled "A- CERVICAL SECTION" is an irregularly outlined, 1.0 x 0.5 x 0.4 cm piece of tan-pink, blood-stained soft tissue. The specimen is embedded in a 3.5 x 2.0 x 1.0 cm aggregate of deep red, well organized clot. The clot is serially sectioned to reveal uniform, deep red, unremarkable surfaces. The specimen is submitted entirely as follows: 1: tissue
2-4: clot

Part B: Received in formalin labeled "B- CX BX 9 O'CLOCK" is a 0.6 x 0.6 x 0.3 cm circular aggregate of tan-white, blood-stained tissue interspersed with fragments of clot. The specimen is submitted in toto in one cassette.

Part C: Received in formalin labeled "C- CX BX 12 O'CLOCK" is 1.0 x 1.0 x 0.3 cm circular aggregate of irregularly outlined fragments of tan-white, blood-stained tissue interspersed with a moderate amount of clot. The specimen is submitted in toto in one cassette.

Part D: Received in formalin labeled "D- ECC" is a cervical biopsy brush with a 1.5 x 1.5 x 0.4 cm circular aggregate of irregularly outlined fragments of tan-white, blood-stained tissue interspersed with mucoid material and clot. The specimen is submitted in toto in one cassette.

Pathology Assistant

Microscopic Description

A-D: Sections show fragments of severely dysplastic squamous epithelium in a papillary configuration, with high grade nuclei and numerous mitotic figures throughout. There is evidence of stromal invasion on parts C and D. The findings on parts A and B are worrisome but not definitive for invasion. The size of the tumor and extent of stromal invasion cannot be further assessed due to the extensive specimen fragmentation. Immunostains (with proper controls) were performed as follows: a stain for CK20 is negative (part D). A stain for ck7 is focally positive (part D). A stain for p16 on part C is positive, which favors a cervical origin.

Intradepartmental consultation: ... has examined this case and agrees with the findings and interpretation.

The staff pathologist listed below reviewed this case.

Pathology Resident

Electronically Signed Out

Staff Pathologist

Result History

Result Date and Time

Status

In process

Priority

Routine

[page 3 of 3]
Report Assistance Message

Results Routing Details for Order

Outcome:	routed using routing scheme	
Routing Scheme Used:		
Routing Scheme Line:	4	
Resulting User:		
Routing Instant:		
Current Status:	Routing Complete	
Status History:	Result contact created Routing started Routing Complete	
Sent:	Message	Recipients:
	Responsible: Yes	
	Provider ID:	provider defined by Results Routing)
	Result routed to linked user	osing
Outcome:	Result not sent	
Resulting User:		
Routing Instant:		
Comments:	An message was not sent because no results were filed	
Current Status:	Routing Complete	
Status History:	Result contact created Routing Complete	

Order Transmittal Details for Order

There is no tracking information for this order. Either the order has not gone through order transmittal or the tracking data has been purged from the system due to age.

Performance Data For

Source: NCI Genomic Data Commons file 200f7cca-71db-4427-b68c-94af526039cb (TCGA-JW-A5VK.00E96283-50FE-4604-A268-FF2A65B58B7F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).